Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A8MJ, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A8MJ-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

* WITH ADDENDUM *

Patient Name:

Med. Rec. #:

DOB:

Soc. Sec. #:

Physician(s):

Visit #:

Sex: Male

Location:

Accession #:

Service Date:

Received:

Client:

FINAL PATHOLOGIC DIAGNOSIS

- A. Prostate, right anterior bladder neck, biopsy: No tumor or benign prostatic gland.
- B. Prostate, right posterior base, biopsy: No tumor or benign prostatic gland.
- C. Prostate, right anterior apex, biopsy:
- 1. No tumor.
- 2. Benign crushed prostatic gland.
- D. Lymph nodes, right external iliac, dissection: Metastatic adenocarcinoma in one of two lymph nodes (1/2); see comment.
- E. Lymph nodes, right obturator, dissection: No tumor identified in seven lymph nodes (0/7).
- F. Lymph nodes, left pelvis, dissection: No tumor identified in seven lymph nodes (0/7).
- G. Prostate and bilateral seminal vesicles, robot-assisted radical prostatectomy:
- 1. Prostatic adenocarcinoma, Gleason score 3+4 = 7, with extra-prostatic extension, negative margins; see comment.
- 2. Bilateral seminal vesicles with invasion by prostatic adenocarcinoma; see comment.

COMMENT:

Synoptic Comment for Prostate Tumors

ICD O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 1/23/14

[page 2 of 4]
- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Left posterior apex, slide G4; left posterior mid gland, slide G8; left posterior, slides G12 and G16; right posterior apex, slide G3; right posterior mid gland, slide G6; right posterior base, slides G10 and G15.
- **Estimated volume of tumor:** 9 cc.
- **Gleason score:** 3+4; primary pattern 3, secondary pattern 4.
- **Estimated volume > Gleason pattern 3:** Greater than 20%.
- **Involvement of capsule:** Tumor invades capsule.
- **Extraprostatic extension:** Tumor present in peri-prostatic fat (slide G6, right posterior mid-gland; slide G10, right posterior base).
- **Margin status for tumor:**
- Negative.
- **Margin status for benign prostate glands:**
- Benign glands present at inked excision margins; right and left apex, slides G1 and G2.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** Present; focally.
- **Tumor involvement of seminal vesicle:** Present, bilaterally.
- **Perineural infiltration:** Present extensively.
- **Lymph node status:**
- Positive;
- Total number of positive nodes: 1.
- Total number of nodes examined: 16.
- **AJCC/UICC stage:** Stage 4 (pT3bN1MX).

Specimen(s) Received

A: Right anterior bladder neck (FS)
B: Right posterior base margin (FS)
C: Right anterior apex margin (FS)
D: Right external iliac nodes
E: Right obturator lymph nodes
F: Left pelvic lymph nodes
G: Prostate & seminal vesicles (fresh)

Intraoperative Diagnosis

FS1 (A) Right anterior bladder neck, biopsy: No tumor or prostatic gland. [REDACTED]
FS2 (B) Right posterior base margin, biopsy: No tumor, no benign prostatic gland. [REDACTED]
FS3 (C) Right anterior apex margin, biopsy: No tumor. Probable crush benign prostatic gland. [REDACTED]

Clinical History

The patient is a [REDACTED] male with prostate cancer undergoing robot-assisted radical prostatectomy and bilateral pelvic lymphadenectomy. Per review of the electronic medical record, the patient has a prior biopsy diagnosis of prostatic adenocarcinoma, Gleason score 3+4 = 7, affecting the right lateral apex, right apex, right lateral mid gland, right mid gland, right lateral base, right mid base, left lateral apex, and left mid gland.

Gross Description

The specimen is received in 7 parts, each labeled with the patient's name and unit number.

Part A, received fresh and labeled "right anterior bladder neck," consists of a single, irregular, unoriented, red-tan tissue fragment (0.7 x 0.5 x 0.4 cm). The specimen is inked black and entirely submitted for frozen section diagnosis 1, and subsequently submitted in cassette A1. [REDACTED]

Part B is received fresh and is labeled "right posterior base margin," and consists of a single, soft,

[page 3 of 4]
Irregular, unoriented piece of red cauterized tissue (0.5 x 0.3 x 0.1 cm). The specimen is entirely frozen for frozen section diagnosis 2 and subsequently submitted in cassette B1. ()

Part C is received fresh and is labeled "right anterior apex margin," and consists of two soft, irregular, unoriented pieces of off-white/tan and red cauterized tissue (0.6 x 0.3 x 0.1 cm in aggregate). The entire specimen is frozen for frozen section diagnosis #3 and subsequently submitted in cassette C1. ()

Part D is received in formalin, additionally labeled "right external iliac nodes." The specimen consists of multiple pieces of unoriented fatty tissue measuring 2.0 x 1.9 x 0.9 cm in aggregate dimension. The tissue is serially processed to reveal no candidate lymph nodes. The tissue is submitted entirely in cassettes D1-D3. ()

Part E is received in formalin, additionally labeled "right obturator lymph node." The specimen consists of multiple pieces of unoriented fatty tissue measuring in aggregate dimension 2.0 x 1.8 x 0.4 cm. There is a single candidate lymph node identified. The tissue is submitted entirely as follows:

Cassette E1: Candidate lymph node, bisected.

Cassettes E2-E3: Remaining fatty tissue. ()

Part F is received in formalin, additionally labeled "left pelvic lymph nodes." The tissue consists of multiple unoriented fragments of fatty tissue with scant pink fibrous tissue. No candidate lymph nodes are identified. The specimen measures in total 0.7 x 1.2 x 2.4 cm. The tissue is submitted entirely in cassettes F1-F3. ()

Part G is received fresh, labeled "prostate and seminal vesicles,"

SPECIMEN TYPE: Prostatectomy.

WEIGHT: 30.5 gm.

SIZE: 4 cm apex to base, 4 cm in width, and 3.5 cm anterior to posterior.

GROSS PATHOLOGIC FINDINGS: The specimen is composed of dense, tan-white, homogeneous parenchyma with no discrete nodules or masses identified. The capsule appears intact. The seminal vesicle/vas deferens bundles (right 2.5 x 2 x 0.5 cm; left 4.0 x 2.0 x 0.5 cm) are normal appearing.

ORIENTED BY: Anatomic landmarks.

INTRAOPERATIVE FINDINGS: Gross only.

INKING:

- Right anterior: Green.

- Left anterior: Blue.

- Posterior: Black.

POTENTIAL STUDIES:

GROSS PHOTOGRAPHS: Yes.

TOTAL NUMBER OF SLICES: 8.

AVERAGE SLICE THICKNESS: 0.5 mm.

CASSETTES: Representative sections are submitted as follows:

G1: Right apex.

G2: Left apex.

G3: Right anterior and posterior quadrants, apex, slice 3.

G4: Left anterior and posterior quadrants, apex, slice 3.

G5: Right anterior quadrant, mid gland, slice 5.

G6: Right posterior quadrant, mid gland, slice 5.

G7: Left anterior quadrant, mid gland, slice 5.

G8: Left posterior quadrant, mid gland, slice 5.

G9: Right anterior base, slice 6.

G10: Right posterior base, slice 6.

G11: Left anterior base, slice 6.

G12: Left posterior base, slice 6.

[page 4 of 4]
G13: Bladder margin.
G14: Bladder margin (submitted entirely with cassette G13).
G15: Right seminal vesicle and prostate.
G16: Left seminal vesicle and prostate.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed out

Addendum.

Date Ordered:

Date Complete:

Date Reported:

Status: Signed Out

By:

Addendum Diagnosis

Addendum Comment

No change in final diagnosis.

Lymph node metastasis is microscopic(< 1mm in diameter) and confined to lymph node. No extranodal extension is identified.

Electronically signed out

Source: NCI Genomic Data Commons file 19bcaa54-364b-4fc8-ad3a-cf01b2248d10 (TCGA-V1-A8MJ.5BF9CF4D-B724-4FFD-A336-ECE60FC80E0D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).